Gene-level copy-number profile of tumor specimen TCGA-NA-A4QX-01A from TCGA case TCGA-NA-A4QX, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IVB; Age at diagnosis: 61.0 years (22,264 days).
Specimen TCGA-NA-A4QX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.ab42c8b4-a3bb-4455-b2e9-2a14f8002e85.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NA-A4QX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7a9cbc17-12a6-4fc3-9cf0-ddd81852caf2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 9,181; copy number 3: 14,014; copy number 4: 30,587; copy number 5: 2,424; copy number 6: 834; copy number 7: 679; copy number 8: 1,017; copy number 9: 375; copy number 11: 272; copy number 15: 53; copy number 21: 378.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NA-A4QX-01A-11D-A28Q-01): tumor purity 0.76, ploidy 3.7, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,078 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:23,951,348–26,013,025, 33 genes, copy number 9: C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, AC010387.2, CDH10, AC091885.2, AC091885.1, AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P.
- chr5:31,093,977–31,559,875, 7 genes, copy number 9 (within-gene range 7–9): AC113386.1, CDH6, DUX4L51, DROSHA, Y_RNA, C5orf22, AC022417.1.
- chr5:42,729,138–43,603,230, 39 genes, copy number 9: AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3.
- chr17:31,860,904–38,751,457, 261 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr17:38,755,279–38,755,400, 1 gene, copy number 9: RNU6-866P.
- chr19:27,638,483–40,808,434, 501 genes, copy number 9–21 (broad region; genes not listed).
- chr19:40,924,219–41,062,444, 5 genes, copy number 11 (within-gene range 2–11): CYP2B7P, AC092071.1, CYP2B6, CYP2A7P1, CYP2G2P.
- chr19:52,031,378–52,095,738, 1 gene, copy number 11 (within-gene range 2–11): ZNF432.
- chr19:52,058,490–54,736,536, 230 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
